Somatic mutation profile of tumor specimen TARGET-30-PASPVZ-09A (aliquot TARGET-30-PASPVZ-09A-01D) from TARGET case TARGET-30-PASPVZ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.6 years (2,043 days).
Specimen TARGET-30-PASPVZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b41b638-47af-4fb2-b71f-e13a338a8f1a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASPVZ-10A (Blood Derived Normal), aliquot TARGET-30-PASPVZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5311d94-db57-4fe7-bb7e-c3558c8668ec

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- GIMAP8 | c.*979G>T | 3'UTR (SNP) | VAF 45/275 reads (16%) | called by muse, mutect2, varscan2
- LPP | c.*243A>T | 3'UTR (SNP) | VAF 71/248 reads (29%) | catalogued as COSV57086289; called by muse, mutect2, varscan2
